Somatic mutation profile of tumor specimen TARGET-30-PALXMM-01A (aliquot TARGET-30-PALXMM-01A-01W) from TARGET case TARGET-30-PALXMM, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.0 years (1,475 days).
Specimen TARGET-30-PALXMM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 664fc5f2-e148-441e-9f1e-3f7b88941b9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALXMM-10A (Blood Derived Normal), aliquot TARGET-30-PALXMM-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7267c57-de84-42e8-b51e-6a42dfe9024a

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG7 | c.1727G>C p.R576P | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61610825, COSV61615135; called by muse, mutect2, varscan2
- ATP9B | c.2242G>T p.V748L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56944696; called by muse, mutect2, varscan2
- MUC16 | c.41493G>T p.K13831N | Missense Mutation (SNP) | VAF 61/410 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.946); catalogued as COSV66689388; called by muse, mutect2, varscan2
- SDR16C5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV58125175; called by muse, mutect2, varscan2
- TDRD3 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 58/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52152603; called by muse, mutect2, varscan2
- ABCA6 | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ARHGEF12 | c.2709A>T p.K903N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CD22 | c.483C>A p.C161* | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- TMEM154 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- VWA5A | c.2211T>A p.N737K | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- KIZ | c.1641C>T p.S547= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, varscan2
- TNK2 | c.375C>T p.D125= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV57365049; called by muse, mutect2, varscan2
- ZFP91 | c.528T>C p.G176= | Silent (SNP) | VAF 17/229 reads (7%) | called by muse, mutect2
